Somatic mutation profile of tumor specimen TARGET-10-PARDXG-09A (aliquot TARGET-10-PARDXG-09A-01D) from TARGET case TARGET-10-PARDXG, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 12.9 years (4,705 days).
Specimen TARGET-10-PARDXG-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 70c01d62-03a1-4871-a506-7412b2e8d46f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARDXG-10A (Blood Derived Normal), aliquot TARGET-10-PARDXG-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3007d4e2-ef77-47fd-8c28-59d7d0bb681c

The open-access MAF lists 16 somatic variants for this specimen: 9 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 4, Intron 3, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAG6 | c.111G>A p.M37I | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT tolerated (0.55); PolyPhen benign (0.25); catalogued as rs1375012237, COSV52987861; called by muse, mutect2
- DST | c.18144G>A p.M6048I (on ENST00000361203 / NM_001374722.1; = p.M3745I on NM_015548.5) | Missense Mutation (SNP) | VAF 41/185 reads (22%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.561); catalogued as rs756410446; called by muse, mutect2, varscan2
- HNF4G | c.259G>T p.D87Y (on ENST00000354370 / NM_001330561.2; = p.D134Y on NM_004133.5) | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62971111; called by muse, mutect2
- IGKV3-20 | c.323A>G p.Y108C | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs759120046; called by muse, mutect2, varscan2
- SERPINB5 | c.37G>A p.V13I | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); catalogued as rs531425323, COSV66975610; called by muse, mutect2
- HMGCLL1 | c.161C>A p.S54* | Nonsense Mutation (SNP) | VAF 23/59 reads (39%) | called by muse, mutect2, varscan2
- PHF23 | c.592dup p.V198Gfs*34 | Frame Shift Ins (INS) | VAF 77/185 reads (42%) | called by mutect2, pindel, varscan2
- TENM2 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- TPTE | c.47A>T p.E16V | Missense Mutation (SNP) | VAF 24/163 reads (15%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CRACR2A | c.69A>G p.P23= | Silent (SNP) | VAF 6/83 reads (7%) | called by muse, mutect2
- MYH1 | c.4131C>A p.T1377= | Silent (SNP) | VAF 12/58 reads (21%) | called by muse, mutect2, varscan2
- NOS1 | c.3678C>T p.D1226= | Silent (SNP) | VAF 29/65 reads (45%) | catalogued as rs781446114, COSV57608028; called by muse, mutect2, varscan2
- TCP11L1 | c.1023A>G p.E341= | Silent (SNP) | VAF 6/22 reads (27%) | called by muse, mutect2, varscan2
- CAPN3 | c.1536+53dup | Intron (INS) | VAF 9/21 reads (43%) | called by mutect2, pindel, varscan2
- KANSL2 | c.-9-105G>T | Intron (SNP) | VAF 24/102 reads (24%) | called by muse, mutect2, varscan2
- KPNA2 | c.1164+72dup | Intron (INS) | VAF 41/116 reads (35%) | called by mutect2, pindel, varscan2
